Somatic mutation profile of tumor specimen 0DIR0I from CCDI case PBBTGA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Olfactory neurocytoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 14.8 years (5,418 days).
Specimen 0DIR0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 254fd8e4-d4fc-47b9-8c66-19147877143e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9a59e57-89c0-4ee9-a3a3-b040edac3a3c

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LANCL1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 543/1269 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs752921141, COSV99286243; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 53/1759 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 61/2038 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CERK | c.1612T>C p.*538Rext*16 | Nonstop Mutation (SNP) | VAF 336/760 reads (44%) | called by muse, mutect2, varscan2
- PCDH11Y | c.636G>T p.K212N (on ENST00000400457 / NM_032973.2; = p.K201N on NM_032971.3) | Missense Mutation (SNP) | VAF 52/808 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.405); called by muse, mutect2
- SEC16A | c.5512C>T p.H1838Y | Missense Mutation (SNP) | VAF 86/715 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- BPIFA3 | c.90C>T p.A30= | Silent (SNP) | VAF 35/1116 reads (3%) | called by muse, mutect2
- LOXHD1 | c.6252C>T p.H2084= (on ENST00000642948; = p.H2022= on NM_144612.7) | Silent (SNP) | VAF 145/1007 reads (14%) | catalogued as rs753440039; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SNRPG | c.-46C>T | 5'UTR (SNP) | VAF 88/574 reads (15%) | catalogued as rs191710102, COSV99232069; called by muse, mutect2, varscan2
